TCGA case TCGA-ER-A19N — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9ee83669-d7a4-476e-8857-304600b4917a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Dead; Days to death: 1,341 days (3.7 years).

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: Progression; Age at diagnosis: 47.9 years (17,480 days); Days to diagnosis: 37 days; Prior treatment: No; Days to last follow up: 1,341 days (3.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.8 years (17,443 days); Year of diagnosis: 2008; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 126 days; Treatment dose: 400 cGy; Number of fractions: 5; Treatment anatomic sites: Regional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 2 of this record; Age at diagnosis: 47.8 years (17,443 days); Prior treatment: Yes.

Follow-up (2 entries)
- Day 0 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,341 days (3.7 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ER-A19N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ER-A19N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 1,170 mg.
  Slide TCGA-ER-A19N-06A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ER-A19N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Follow-up form: Lost to follow-up: No.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,341 days; disease-specific survival: no event (censored), 1,341 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ER-A19N-06A-11D-A191-01): tumor purity 0.35, ploidy 2.31, whole-genome doublings 0.
